Somatic mutation profile of tumor specimen 0DOV97 from CCDI case PBCCRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.8 years (649 days).
Specimen 0DOV97: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fafc4dc-f4f4-4c1d-924b-668734670c5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6952610-9aa1-4278-b1b4-467ee9050fde

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRPA1 | c.448T>A p.L150M | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100084639; called by muse, mutect2, varscan2
- C4orf54 | c.4264G>C p.E1422Q | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CNTN5 | c.824T>A p.V275E | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GRAMD1A | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 133/749 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HNRNPF | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 21/586 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDHGA3 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 108/736 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EIF3B | chr7:2354116 C>T | 5'Flank (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- MICALL2 | c.-59G>A | 5'UTR (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- MICALL2 | c.-60G>A | 5'UTR (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.428-23G>T | Intron (SNP) | VAF 152/787 reads (19%) | catalogued as COSV52462398; called by muse, mutect2, varscan2
